Somatic mutation profile of tumor specimen TCGA-HT-7475-01A (aliquot TCGA-HT-7475-01A-11D-2024-08) from TCGA case TCGA-HT-7475, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 67.6 years (24,686 days).
Specimen TCGA-HT-7475-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6783772d-d2bb-4a6c-8a0e-7f439272d254.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7475-10A (Blood Derived Normal), aliquot TCGA-HT-7475-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7c14e22-4c5a-4f59-bec5-8fa8d82ba79e

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 31, Silent 13, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.623A>G p.D208G | Missense Mutation (SNP) | VAF 17/51 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1464727668, COSV52685550, COSV52708074, COSV52744439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.329G>C p.R110P | Missense Mutation (SNP) | VAF 22/65 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADA2 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as rs369306297; called by muse, mutect2, varscan2
- AHNAK2 | c.12193G>A p.D4065N | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV60916022; called by muse, mutect2, varscan2
- AKAP9 | c.11606C>T p.P3869L (on ENST00000359028; = p.P3845L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/131 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.429); catalogued as COSV50151829; called by muse, mutect2, varscan2
- ATAD3B | c.689G>A p.R230K (on ENST00000308647; = p.R336K on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV58020867; called by muse, mutect2, varscan2
- ATRX | c.6545A>G p.K2182R | Missense Mutation (SNP) | VAF 69/79 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64876939; called by muse, mutect2, varscan2
- BMP2K | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as rs758686262, COSV58595416; called by muse, mutect2, varscan2
- C2 | c.1455+2T>C p.X485_splice | Splice Site (SNP) | VAF 25/55 reads (45%) | catalogued as rs761681406, COSV100191127; called by muse, mutect2, varscan2
- CD300LB | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs373107448; called by muse, mutect2, varscan2
- COL22A1 | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755922675, COSV57337890; called by muse, mutect2, varscan2
- DSG1 | c.564C>A p.N188K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1486109586, COSV57135590; called by muse, mutect2, varscan2
- DUSP29 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 39/96 reads (41%) | catalogued as COSV58300652; called by muse, mutect2, varscan2
- EZH1 | c.1023+1G>T p.X341_splice | Splice Site (SNP) | VAF 21/50 reads (42%) | catalogued as COSV70549492, COSV70550968; called by muse, mutect2, varscan2
- FANCE | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs369035099; called by muse, mutect2, varscan2
- HPS6 | c.854T>G p.F285C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54625684; called by muse, mutect2, varscan2
- IL1RL1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as COSV52115964; called by muse, mutect2, varscan2
- KLKB1 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1326484987, COSV52994150; called by muse, mutect2
- KMT2B | c.3704G>A p.R1235Q | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as COSV55861395; called by muse, mutect2, varscan2
- LRIF1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 50/132 reads (38%) | catalogued as rs375319628; called by muse, mutect2, varscan2
- LRP1 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs937133751, COSV54505729; called by muse, mutect2
- MACROD2 | c.698A>T p.K233I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV53987801, COSV99439032; called by muse, mutect2, varscan2
- PHF21A | c.1489A>G p.S497G (on ENST00000418153 / NM_001101802.3; = p.S451G on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.028); catalogued as COSV57654126; called by muse, mutect2, varscan2
- PIK3CG | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs753756610, COSV63248741, COSV63250289; called by muse, mutect2, varscan2
- PKHD1L1 | c.9352G>A p.E3118K | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV65740210; called by muse, varscan2
- PTH2R | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55916327, COSV99782419; called by muse, mutect2, varscan2
- PTPRM | c.664-1G>A p.X222_splice | Splice Site (SNP) | VAF 43/99 reads (43%) | catalogued as COSV59860119; called by muse, mutect2, varscan2
- SARAF | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.823); catalogued as rs1261354105, COSV56357428; called by muse, mutect2
- SCNN1B | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56304670; called by muse, mutect2, varscan2
- STPG1 | c.29G>A p.R10H (on ENST00000337248 / NM_001199013.2; = p.A3T on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1245180295, COSV50219597; called by muse, mutect2, varscan2
- USP35 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as COSV71572806; called by muse, mutect2, varscan2
- ZMAT4 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1419897637, COSV52695626; called by muse, mutect2, varscan2
- ZNF567 | c.173T>G p.L58W (on ENST00000536254 / NM_001322913.1; = p.L27W on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62445398; called by muse, mutect2, varscan2
- ZNF600 | c.1579A>G p.K527E | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57742812; called by muse, mutect2
- EIF4A1 | c.133del p.R45Vfs*28 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | called by mutect2, pindel, varscan2
- PREP | c.588G>A p.W196* (on ENST00000369110; = p.W262* on NM_002726.5) | Nonsense Mutation (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- SMOC1 | c.449_450del p.S150Cfs*4 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- SULT1C2 | c.501del p.V168Wfs*10 | Frame Shift Del (DEL) | VAF 27/110 reads (25%) | called by pindel, varscan2
- THBS3 | c.1144_1175del p.C382Gfs*43 | Frame Shift Del (DEL) | VAF 24/269 reads (9%) | called by mutect2, pindel
- TRDV1 | c.44A>G p.Y15C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF454 | c.810_819del p.K270Nfs*95 | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | called by mutect2, pindel, varscan2
- AP002512.3 | c.15C>T p.T5= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs559337190, COSV56566892; called by muse, mutect2, varscan2
- ART3 | c.786A>G p.L262= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV61914134; called by muse, mutect2, varscan2
- CABS1 | c.1044T>C p.N348= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV56733661; called by muse, mutect2, varscan2
- EBF1 | c.1290C>T p.H430= | Silent (SNP) | VAF 42/83 reads (51%) | catalogued as rs570120838, COSV58171050; called by muse, mutect2, varscan2
- FGF20 | c.621A>G p.L207= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV51661449; called by muse, mutect2, varscan2
- KMT2D | c.1215A>G p.Q405= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV56442008; called by muse, mutect2, varscan2
- MPO | c.135C>T p.P45= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV56564162; called by muse, mutect2, varscan2
- NOL4 | c.291A>G p.L97= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs748903934, COSV52347485; called by muse, mutect2, varscan2
- OR4D6 | c.102G>T p.V34= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as COSV55659852, COSV55660016; called by muse, mutect2
- PIK3R2 | c.873C>T p.H291= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV55848046; called by muse, mutect2, varscan2
- TNFRSF1A | c.1236G>A p.P412= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV50601131; called by muse, mutect2, varscan2
- TPTE | c.96C>T p.T32= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as rs571891150; called by muse, mutect2, varscan2
- UAP1 | c.1012C>T p.L338= | Silent (SNP) | VAF 68/262 reads (26%) | catalogued as COSV54850760; called by muse, mutect2, varscan2
